Surgical pathology report (de-identified scan), TCGA case TCGA-56-A4ZK, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-A4ZK-01A (Primary Tumor).

[page 1 of 2]
INFORMATION

Accession #:

Acct / Reg #

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Right lower lobe nodule, biopsy with frozen section:
Squamous cell carcinoma.
Frozen section diagnosis confirmed.

- B. Right lower lobe, lobectomy:

Tumor Characteristics:

1. Histologic type: Squamous cell carcinoma.
2. Histologic grade: High-grade/poorly differentiated.
3. Tumor site: Right lower lobe.
4. Tumor focality: Unifocal.
5. Tumor size: 2.2 x 2.0 x 1.5 cm.
6. Visceral pleural invasion: Yes (See comment)
7. Lymphovascular space invasion: No.
8. Tumor extension: Tumor is confined to the lung.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Tumor distance from bronchial margin: 5.2 cm
2. Tumor distance from parenchymal (stapled) margin: 2.9 cm.
3. Tumor distance from pleural surface: Positive.

Lymph Node Status:

1. Total number of lymph nodes received: 13 (includes all parts as well as 9 nodes in the lobectomy specimen).
2. Total number of lymph nodes containing metastatic carcinoma: 0 (0/13).

Other:

1. Other significant findings: Inflammatory response to tumor includes extensive multinucleated giant cell/histiocyte reaction with ill-defined epithelioid microgranulomas. Subpleural and septal fibrosis, and areas of bronchial metaplasia and chronic inflammation.
2. pTNM stage: T2 N0 M0. (Neoplasm is staged as T2 based on pleural invasion).

- C. Level 9 lymph node, biopsy:

One lymph node, negative for metastatic tumor (0/1).

- D. Level 7 lymph nodes, biopsy:

Seven lymph nodes, negative for metastatic tumor (0/7).

- E. Level 4R lymph node, biopsy:

Two lymph nodes, negative for metastatic tumor (0/2).

Electronic Signature: [Redacted]

COMMENTS:

The neoplasm is poorly differentiated with nests of mostly solid tumor, with eosinophilic cytoplasm and areas of apparent intercellular bridges. A squamous cell carcinoma is favored, however to further evaluate and exclude an adenocarcinoma component, immunostains are performed (control slides stain appropriately).

The neoplasm stains strongly positive for p63 and CK5/6.

A TTF-1 and Napsin immunostain are both negative in the neoplasm.

These findings support a squamous cell carcinoma.

The tumor extends to the pleural surface. (an elastic stain on block B4 shows tumor ruptures through elastic tissue-loss of elastic staining, confirm of invasion of visceral pleura.

1 CD-0-3
carcinoma, squamous cell, NOS 8070/3
Site: lung, @ lower lobe C34.3

AW
11/4/12

[page 2 of 2]
SPECIMEN INFORMATION

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Other lung disease

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Right lower lobe nodule

B. Right lower lobe

C. Level 9 lymph node

D. Level 7 lymph node

E. Level 4R lymph node

SPECIMEN DATA

GROSS DESCRIPTION:

A. The first container A is received in formalin labeled with the patient's name 'right lower lobe nodule.' The specimen consists of three gray-tan core biopsies measuring up to 1.0 cm in greatest dimension. The specimen was examined at the time of surgery and the frozen section is subsequently entirely submitted in cassette

B. The second container B is received in formalin labeled with the patient's name 'right lower lobe.' The specimen consists of a lung lobectomy specimen with lower lobe measuring 16.5 x 9.0 x 3.5 cm and weighs 236 grams. The pleural surface is gray-tan to brown-tan, slightly anthracotic. There is an area of puckering noted within the central portion measuring 2.0 x 1.5 cm. The pleura has been inked. Sectioning reveals a circumscribed gray-tan slightly anthracotic mass that measures 2.2 x 2.0 x 1.5 cm that abuts the pleural surface, is 5.2 cm from the bronchial margin of resection and within 2.3 cm of the closest staple line. The mass corresponds to the puckered area noted on the pleural surface. The surrounding lung tissue is red-tan spongy, congested. There are no other lesions grossly identified. Within the parabronchial soft tissue there are two gray-tan nodules consistent with lymph nodes 0.3 and 1.4 cm. The largest is bisected. Received with the specimen are two cassettes, one green and one yellow labeled 'Representative sections are submitted in cassettes labeled as follows: section from mass in blocks 1 through 4; shave section from the staple line resection in block 5; bronchial vascular margin block 6; surrounding uninvolved lung block 7; sections from each of the lymph nodes (largest bisected) in block 8.'

C. Container C is received in formalin labeled 'level 9.' The specimen consists of a gray-tan to brown-tan anthracotic nodule consistent with lymph node 1.5 x 0.7 x 0.5 cm. The lymph node is bisected and is entirely submitted in a single cassette

D. The fourth container D is received in formalin labeled 'level 7 lymph node.' The specimen consists of seven gray-tan to brown-tan anthracotic nodules consistent with lymph nodes that measure from 0.3 to 1.1 cm in greatest dimension. The lymph nodes are entirely submitted in cassettes labeled as follows: three probable nodes block 1; two probable nodes each bisected block 2; two probable nodes each bisected block 3.

E. The fifth container E is received in formalin labeled 'level 4R lymph node.' The specimen consists of two brown-tan anthracotic nodules consistent with lymph nodes measuring 0.7 and 0.9 cm in greatest dimension. The lymph nodes are each bisected, entirely submitted in a single cassette labeled

INTRA-OPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS: Part A. Non-small cell carcinoma per

F

	Yes	No
Ch. 1/12		

Source: NCI Genomic Data Commons file 577840ea-716c-4f6f-9ea8-37e867fa305c (TCGA-56-A4ZK.3F2B148C-7611-4F00-9483-B05A1CFD9EEF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).